Gene-level copy-number profile of tumor specimen TCGA-CV-6954-01A from TCGA case TCGA-CV-6954, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.0 years (21,557 days).
Specimen TCGA-CV-6954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.cc4d0b3d-2ccc-4978-bec7-3dcfd257c63f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6954-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cff8b8b4-8203-402d-982e-3a1fad8f962a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 2,394; copy number 2: 14,122; copy number 3: 30,203; copy number 4: 4,996; copy number 5: 3,677; copy number 6: 1,525; copy number 7: 1,318; copy number 8: 269; copy number 9: 978; copy number 11: 72; copy number 12: 27; copy number 13: 41; copy number 14: 122; copy number 23: 37; copy number 25: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6954-01A-11D-1910-01): tumor purity 0.49, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,587,794–188,681,051, 30 genes (within-gene range 0–3): FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3.
- chr10:34,201,979–34,202,074, 1 gene: Y_RNA.
- chr13:100,089,015–100,530,437, 1 gene (within-gene range 0–4): PCCA.
- chr13:100,338,982–100,481,205, 2 genes: AL353697.1, PCCA-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,867 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–471,937, 18 genes, copy number 11: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3.
- chr5:10,168,783–28,287,807, 224 genes, copy number 8–9 (broad region; genes not listed).
- chr5:38,025,568–45,895,970, 122 genes, copy number 14 (broad region; genes not listed).
- chr6:167,607–29,431,967, 648 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:44,809,317–63,779,336, 234 genes, copy number 7–11 (broad region; genes not listed).
- chr6:63,797,189–64,412,779, 4 genes, copy number 7–11: AL354719.1, SCAT8, GCNT1P4, AL357375.1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 7 (within-gene range 2–7): UNC5D.
- chr8:35,525,176–38,996,824, 82 genes, copy number 7–12 (broad region; genes not listed).
- chr8:39,018,615–39,018,683, 1 gene, copy number 12: SNORD38D.
- chr8:40,900,016–43,674,591, 82 genes, copy number 7–13 (broad region; genes not listed).
- chr11:100,641,975–103,479,863, 60 genes, copy number 8 (within-gene range 3–8): RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr18:20,946,906–27,190,698, 125 genes, copy number 7–25 (broad region; genes not listed).
- chr20:6,200,989–64,313,132, 1,266 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
